Somatic mutation profile of tumor specimen ALCH-AENP-TTP1-A (aliquot ALCH-AENP-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AENP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,757 days).
Specimen ALCH-AENP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 969ab469-98be-4096-8be1-567ce8e98ca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENP-NB1-A (Blood Derived Normal), aliquot ALCH-AENP-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/150fcaf3-ac1d-4d79-bae6-001b5fb072b1

The open-access MAF lists 336 somatic variants for this specimen: 237 protein-altering or splice-affecting, 63 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 63, Frame Shift Del 18, Intron 15, Nonsense Mutation 14, Splice Site 6, 3'UTR 6, RNA 5, 5'UTR 4, 5'Flank 3, 3'Flank 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 202/751 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRMU | c.478+1G>A p.X160_splice | Splice Site (SNP) | VAF 18/401 reads (4%) | catalogued as rs1569072157; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA3 | c.3065G>C p.R1022P | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.828); catalogued as rs762690602, COSV100068696; called by muse, mutect2, varscan2
- ADGRL4 | c.206G>T p.C69F | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1022468810; called by muse, mutect2, varscan2
- AFDN | c.3211C>G p.Q1071E | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60042878; called by muse, mutect2
- AK7 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs530586124, COSV50880749; called by muse, mutect2, varscan2
- ALK | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs75158395; called by muse, mutect2
- AMPH | c.1840del p.E614Rfs*55 | Frame Shift Del (DEL) | VAF 46/247 reads (19%) | catalogued as COSV100341269, COSV57744029; called by mutect2, pindel, varscan2
- ANO5 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 123/511 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as rs139563739; called by muse, mutect2, varscan2
- ANO6 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 78/521 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775289465; called by muse, mutect2, varscan2
- APC | c.2429G>T p.R810M | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV57334784; called by muse, mutect2, varscan2
- C1QTNF5 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1178933033; called by muse, mutect2, varscan2
- CALCR | c.1319G>T p.R440L (on ENST00000649521 / NM_001164737.2; = p.R424L on NM_001742.4) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs748926357, COSV64005918; called by muse, mutect2, varscan2
- CCDC154 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs777908652; called by muse, mutect2, varscan2
- CD96 | c.1369T>C p.S457P (on ENST00000283285 / NM_198196.3; = p.S441P on NM_005816.5) | Missense Mutation (SNP) | VAF 65/511 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs150804090; called by muse, mutect2, varscan2
- CFAP47 | c.2819C>G p.A940G | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV52884827; called by muse, mutect2, varscan2
- CFTR | c.3896C>T p.T1299I | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs397508634, CM992307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN5 | c.724-2A>G p.X242_splice | Splice Site (SNP) | VAF 136/292 reads (47%) | catalogued as CS157827; called by muse, mutect2, varscan2
- CLEC14A | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100643464; called by muse, mutect2, varscan2
- COPA | c.1748G>T p.R583M | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99614859; called by muse, mutect2, varscan2
- CT47B1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 142/239 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as rs9698608, COSV100989020, COSV64891022; called by muse, mutect2, varscan2
- CXCL17 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); catalogued as rs538690041; called by muse, mutect2, varscan2
- DOCK10 | c.5066C>A p.A1689E | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51424978; called by muse, mutect2
- DUSP22 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740019, COSV60525748; called by muse, mutect2, varscan2
- EPHA6 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.127); catalogued as COSV67561940; called by muse, mutect2, varscan2
- EYS | c.2262C>A p.S754R | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV65537435; called by muse, varscan2
- FASTKD3 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV52946019; called by muse, mutect2
- FOXL2 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 87/493 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100374369, COSV57728033; called by muse, mutect2, varscan2
- GLYATL1 | c.623C>A p.A208D (on ENST00000317391 / NM_001354699.1; = p.A239D on NM_080661.4) | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV104397136; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 86/621 reads (14%) | SIFT tolerated, low confidence (0.16); catalogued as rs1161473519; called by muse, mutect2, varscan2
- GPA33 | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs141668937; called by muse, mutect2, varscan2
- GPR149 | c.1618del p.R540Vfs*36 | Frame Shift Del (DEL) | VAF 56/190 reads (29%) | catalogued as COSV67666905; called by mutect2, pindel
- GPR55 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV67407963; called by muse, mutect2, varscan2
- GRIK3 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs757906633, COSV66138026; called by muse, mutect2, varscan2
- GRK5 | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV64867192, COSV64868173; called by muse, mutect2, varscan2
- IGKV2D-30 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 218/783 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs369396815; called by muse, mutect2, varscan2
- KCNB2 | c.966G>C p.Q322H | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73051538; called by muse, mutect2, varscan2
- LAMA1 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs776368738, COSV67541780; called by muse, mutect2, varscan2
- LRP1B | c.8185G>A p.A2729T | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs372667614, COSV101256084, COSV101257161, COSV67201434; called by muse, mutect2
- MARK1 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 190/446 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs767289212, COSV65071720; called by muse, mutect2, varscan2
- MDGA2 | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as COSV101229674; called by muse, mutect2, varscan2
- MFN1 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.06); catalogued as rs151151919; called by muse, mutect2, varscan2
- MGAT3 | c.965C>A p.P322Q | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57864920; called by muse, mutect2, varscan2
- MYH7 | c.4075C>T p.R1359C | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs45451303, CM081704, COSV100806166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO7A | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 45/231 reads (19%) | catalogued as rs1555062924, CM061144; called by muse, mutect2, varscan2
- NCAM2 | c.1637G>C p.R546P | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV53064796; called by muse, mutect2, varscan2
- NRXN2 | c.2597C>T p.T866M | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376826316, COSV55453967; called by muse, mutect2, varscan2
- NSUN2 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs1181217907, COSV99242934; called by muse, mutect2, varscan2
- NUDT16 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/185 reads (16%) | SIFT deleterious, low confidence (0.01); catalogued as rs775999600, COSV63248217; called by muse, mutect2, varscan2
- OR10H4 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780558033; called by muse, mutect2, varscan2
- OR2C3 | c.775A>T p.M259L | Missense Mutation (SNP) | VAF 236/637 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100825676; called by muse, mutect2
- OR2G2 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 135/360 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60741672, COSV60742813; called by muse, varscan2
- OR4A16 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV100125459; called by muse, mutect2, varscan2
- OR4F6 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV61027349; called by muse, mutect2, varscan2
- OR5J2 | c.249del p.N84Tfs*5 | Frame Shift Del (DEL) | VAF 36/192 reads (19%) | catalogued as COSV104394825; called by mutect2, pindel, varscan2
- PDE1C | c.1614G>C p.K538N | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV99061752; called by muse, mutect2, varscan2
- PIK3C2G | c.3013C>A p.Q1005K (on ENST00000676171; = p.Q964K on NM_004570.5) | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as rs1374460535, COSV99854189; called by muse, mutect2, varscan2
- PLEKHH1 | c.845G>A p.W282* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as rs1369958807, COSV100232659; called by muse, mutect2, varscan2
- POM121L12 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV68693491; called by muse, mutect2, varscan2
- PRUNE2 | c.2859C>A p.N953K | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65042418, COSV65044639; called by muse, mutect2, varscan2
- PSMD1 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58077802; called by muse, varscan2
- PXDNL | c.3280G>T p.E1094* | Nonsense Mutation (SNP) | VAF 115/324 reads (35%) | catalogued as COSV62493530; called by muse, mutect2, varscan2
- RFX7 | c.1295C>G p.A432G (on ENST00000559447 / NM_001368074.1; = p.A529G on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/470 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57968333; called by muse, mutect2, varscan2
- RYR1 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs781271902, COSV62094048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERBP1 | c.850G>A p.G284S (on ENST00000370995 / NM_001018067.2; = p.G263S on NM_015640.4) | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.528); catalogued as rs749718037; called by muse, mutect2, varscan2
- SFTPA1 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs766406814; called by muse, mutect2, varscan2
- SLC8A3 | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs769544455; called by muse, mutect2, varscan2
- SNRPA | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 14/425 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV54681755; called by muse, mutect2
- STON1-GTF2A1L | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 142/466 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1465887331; called by muse, mutect2, varscan2
- SYNE1 | c.17825G>A p.R5942H (on ENST00000367255 / NM_182961.4; = p.R5871H on NM_033071.3) | Missense Mutation (SNP) | VAF 233/647 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746220387, COSV54932786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCN1 | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 187/696 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.17); catalogued as COSV57252206; called by muse, mutect2, varscan2
- TECRL | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV67089766; called by muse, mutect2, varscan2
- TEX26 | c.228C>A p.Y76* | Nonsense Mutation (SNP) | VAF 146/329 reads (44%) | catalogued as COSV66839966; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 62/164 reads (38%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TPSD1 | c.153del p.W51Cfs*3 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | catalogued as rs1393669275; called by mutect2, pindel, varscan2
- TRAV18 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs374480948; called by muse, mutect2, varscan2
- TTN | c.58687C>A p.P19563T (on ENST00000591111; = p.P12139T on NM_003319.4) | Missense Mutation (SNP) | VAF 40/200 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV59872427; called by muse, mutect2, varscan2
- UBE3C | c.258del p.I88Lfs*11 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | catalogued as rs1344771317; called by mutect2, pindel, varscan2
- UPB1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs121908066, CM080592; called by muse, mutect2, varscan2
- XCL1 | c.227G>T p.W76L | Missense Mutation (SNP) | VAF 37/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892197; called by muse, mutect2
- ZAR1L | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV61526328; called by muse, mutect2, varscan2
- ZCCHC3 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV66642891; called by muse, mutect2
- ZFP64 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99401963; called by muse, mutect2, varscan2
- ZNF721 | c.881C>A p.T294K (on ENST00000338977; = p.T306K on NM_133474.4) | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as rs1241660540, COSV59091912; called by muse, mutect2
- ZNF98 | c.467A>T p.Y156F | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV63334189; called by muse, varscan2
- ADAM22 | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS9 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.1843T>A p.C615S | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD24 | c.2072G>T p.G691V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANKRD30A | c.1757C>T p.T586I (on ENST00000611781; = p.T530I on NM_052997.2) | Missense Mutation (SNP) | VAF 41/688 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2
- ASPM | c.8906G>C p.R2969T | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ASPM | c.4301G>T p.W1434L | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- AVPI1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAHD1 | c.162_176del p.N54_R58del | In Frame Del (DEL) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- C8A | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 20/430 reads (5%) | called by muse, mutect2
- CABS1 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CCDC150 | c.1127_1137+1del | In Frame Del (DEL) | VAF 100/313 reads (32%) | called by mutect2, pindel, varscan2
- CCNT1 | c.2035A>C p.T679P | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1C | c.110T>A p.V37D | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CHD7 | c.3810del p.E1271Kfs*15 | Frame Shift Del (DEL) | VAF 46/402 reads (11%) | called by mutect2, pindel, varscan2
- CIAO3 | c.192_195del p.K65Sfs*3 | Frame Shift Del (DEL) | VAF 48/176 reads (27%) | called by mutect2, pindel, varscan2
- CIBAR2 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIC | c.3835C>T p.P1279S | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- CKB | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- COL16A1 | c.4051A>G p.K1351E | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL22A1 | c.4366G>T p.G1456W | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CR1 | c.3121T>A p.S1041T | Missense Mutation (SNP) | VAF 238/622 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CSMD1 | c.614A>T p.E205V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CSMD2 | c.3278G>T p.R1093M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCC | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 69/468 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMD | c.6520T>C p.S2174P | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- DNAH6 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, varscan2
- DPP6 | c.1360del p.Q454Rfs*34 (on ENST00000377770 / NM_001364500.2; = p.Q392Rfs*34 on NM_001936.5) | Frame Shift Del (DEL) | VAF 58/187 reads (31%) | called by mutect2, pindel, varscan2
- ECD | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EP300 | c.4961dup p.M1654Ifs*19 | Frame Shift Ins (INS) | VAF 50/296 reads (17%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.1081A>G p.S361G | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- EQTN | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ERICH3 | c.2212C>A p.L738I | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, varscan2
- FAM155A | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FAT2 | c.2857G>A p.D953N | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD4 | c.836G>T p.W279L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FMN1 | c.3840T>A p.S1280R (on ENST00000616417 / NM_001277313.2; = p.S1057R on NM_001103184.4) | Missense Mutation (SNP) | VAF 99/372 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FRAS1 | c.7521G>A p.Q2507= | Splice Region (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- FUT5 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FXR1 | c.485A>C p.H162P | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GALT | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- GBA3 | c.622T>A p.Y208N | Missense Mutation (SNP) | VAF 163/370 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GLI3 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GNE | c.1549C>A p.L517M (on ENST00000396594 / NM_001128227.3; = p.L486M on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 235/1038 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 75/458 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GOLGB1 | c.6767+1G>T p.X2256_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | called by muse, varscan2
- GRAMD1C | c.1028T>G p.F343C | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRM3 | c.638T>G p.V213G | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD4 | c.8032G>A p.E2678K | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- HHIPL2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 58/520 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HIVEP1 | c.3775A>C p.K1259Q | Missense Mutation (SNP) | VAF 205/460 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- HIVEP1 | c.4642G>T p.G1548W | Missense Mutation (SNP) | VAF 153/304 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- HK1 | c.1951G>T p.V651L | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- HMCN2 | c.11419T>C p.Y3807H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IK | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IL1RAPL1 | c.2078G>C p.S693T | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- INSYN2B | c.1402A>G p.T468A | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IRS2 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.94); PolyPhen benign (0.234); called by mutect2, varscan2
- KCNAB1 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 182/932 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDR | c.3115A>T p.K1039* | Nonsense Mutation (SNP) | VAF 124/376 reads (33%) | called by muse, varscan2
- KIAA1210 | c.3602C>A p.A1201E | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- KIAA1210 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.191); called by muse, mutect2
- KIT | c.2802+1G>C p.X934_splice | Splice Site (SNP) | VAF 127/456 reads (28%) | called by muse, mutect2, varscan2
- KLHL23 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- KLHL33 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- KLK5 | c.610dup p.L204Pfs*24 | Frame Shift Ins (INS) | VAF 146/362 reads (40%) | called by mutect2, pindel, varscan2
- KMT2D | c.13734del p.F4579Lfs*13 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- KNCN | c.152-2A>T p.X51_splice | Splice Site (SNP) | VAF 62/293 reads (21%) | called by muse, mutect2, varscan2
- LEPR | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- LRP5 | c.826A>G p.S276G | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRK1 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP1B | c.7010C>T p.A2337V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, varscan2
- MED13 | c.5831T>C p.M1944T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MEX3B | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MGAT4D | c.889A>T p.R297* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- MTHFSD | c.850G>T p.G284* (on ENST00000360900 / NM_001159377.2; = p.G283* on NM_022764.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.38360T>C p.L12787P | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC16 | c.21097C>A p.Q7033K | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYH7 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 138/461 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM2 | c.2387C>A p.P796H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NCK1 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 36/326 reads (11%) | called by muse, mutect2, varscan2
- NCKAP5L | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOVA1 | c.1266T>A p.D422E | Missense Mutation (SNP) | VAF 147/531 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NPR2 | c.198T>A p.F66L | Missense Mutation (SNP) | VAF 104/412 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRG3 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- NRG3 | c.868T>A p.C290S | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OCEL1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OGDHL | c.2486G>T p.R829L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OLA1 | c.1079del p.N360Mfs*40 | Frame Shift Del (DEL) | VAF 65/216 reads (30%) | called by mutect2, pindel, varscan2
- OR1S2 | c.421del p.H141Tfs*3 | Frame Shift Del (DEL) | VAF 87/385 reads (23%) | called by mutect2, pindel, varscan2
- OR2C3 | c.777G>T p.M259I | Missense Mutation (SNP) | VAF 238/634 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2
- OR4D5 | c.449T>A p.V150E | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR51F2 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- OR51G2 | c.936T>A p.F312L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, varscan2
- OR5H2 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PACS2 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCDH15 | c.3545G>A p.R1182K | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.38); called by muse, varscan2
- PCDH17 | c.3182C>A p.P1061Q | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PCDHB1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDHB16 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 36/216 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- PHF20 | c.1478A>T p.H493L | Missense Mutation (SNP) | VAF 86/420 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PKD1L3 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PLCB1 | c.2202del p.F734Lfs*12 | Frame Shift Del (DEL) | VAF 71/352 reads (20%) | called by mutect2, varscan2
- PPP1R3A | c.2878del p.I960Sfs*23 | Frame Shift Del (DEL) | VAF 83/455 reads (18%) | called by pindel, varscan2*
- PRKDC | c.8342C>T p.P2781L | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSIP1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PSMD5 | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- PTP4A3 | c.231del p.G78Afs*3 | Frame Shift Del (DEL) | VAF 77/197 reads (39%) | called by mutect2, pindel, varscan2
- PTPRO | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 70/365 reads (19%) | called by muse, mutect2, varscan2
- RB1 | c.2434_2456del p.P812Afs*18 | Frame Shift Del (DEL) | VAF 156/565 reads (28%) | called by mutect2, pindel, varscan2
- RCC2 | c.362A>T p.E121V | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); called by muse, varscan2
- RPL24 | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RUBCNL | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 244/496 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR3 | c.3287G>T p.G1096V | Missense Mutation (SNP) | VAF 120/521 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SHCBP1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.139); called by muse, varscan2
- SHISA9 | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.735); called by muse, varscan2
- SLC35C1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 42/243 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SLC4A4 | c.3059A>T p.K1020M (on ENST00000264485 / NM_001098484.3; = p.K976M on NM_003759.4) | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SLC6A19 | c.1271T>A p.L424H | Missense Mutation (SNP) | VAF 23/844 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC7A9 | c.923T>C p.F308S | Missense Mutation (SNP) | VAF 200/447 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.241); called by muse, varscan2
- SLC8B1 | c.1559T>A p.L520Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLC9A9 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SMG5 | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- SPTAN1 | c.4482dup p.N1495* | Frame Shift Ins (INS) | VAF 133/582 reads (23%) | called by mutect2, pindel, varscan2
- STRN4 | c.2144A>T p.Q715L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYBU | c.463G>A p.G155S (on ENST00000276646 / NM_001099754.2; = p.G154S on NM_017786.6) | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TARS1 | c.800G>C p.R267T | Missense Mutation (SNP) | VAF 58/737 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAS2R8 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TGFBR3 | c.2024A>T p.H675L | Missense Mutation (SNP) | VAF 57/421 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TMOD2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TMPO | c.870+1G>A p.X290_splice (on ENST00000343315 / NM_001307975.2; = p.X330_splice on NM_001032283.3) | Splice Site (SNP) | VAF 63/447 reads (14%) | called by muse, mutect2, varscan2
- TRIML1 | c.1213T>A p.C405S | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.80888C>A p.P26963Q (on ENST00000591111; = p.P19539Q on NM_003319.4) | Missense Mutation (SNP) | VAF 23/234 reads (10%) | PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TTN | c.58688C>A p.P19563H (on ENST00000591111; = p.P12139H on NM_003319.4) | Missense Mutation (SNP) | VAF 40/205 reads (20%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.45427C>G p.Q15143E (on ENST00000591111; = p.Q7719E on NM_003319.4) | Missense Mutation (SNP) | VAF 63/341 reads (18%) | PolyPhen benign (0.352); called by muse, mutect2, varscan2
- TUSC1 | c.417C>A p.N139K | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.125); called by muse, mutect2
- U2SURP | c.2273del p.P758Hfs*68 | Frame Shift Del (DEL) | VAF 97/392 reads (25%) | called by mutect2, pindel, varscan2
- UNC80 | c.3484C>A p.L1162I | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP8 | c.1606_1610del p.E536* | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- VCP | c.1696-5T>C | Splice Region (SNP) | VAF 48/339 reads (14%) | called by muse, mutect2, varscan2
- VPS35L | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- VSIG2 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- VWC2L | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- VWDE | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.4142A>T p.Q1381L | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, varscan2
- ZNF19 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF609 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- ZNF726 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF727 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.124); called by muse, varscan2
- ZNF790 | c.763A>C p.K255Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZSCAN4 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 124/353 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADAMTS19 | c.630G>C p.T210= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs773298842; called by muse, mutect2, varscan2
- ADAMTS5 | c.2415C>G p.V805= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV53178383; called by muse, mutect2, varscan2
- ASF1B | c.423C>T p.A141= | Silent (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- BIRC6 | c.3513T>C p.C1171= | Silent (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- CACNA1H | c.1623C>T p.P541= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs773501953; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNB3 | c.909C>G p.L303= | Silent (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- CACNG8 | c.447C>T p.S149= | Silent (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- CNGB1 | c.2121C>T p.T707= | Silent (SNP) | VAF 75/489 reads (15%) | catalogued as rs748402322; called by muse, mutect2, varscan2
- CNOT6L | c.610C>A p.R204= (on ENST00000504123 / NM_001286790.2; = p.R199= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/177 reads (25%) | called by muse, mutect2, varscan2
- COL4A4 | c.2943A>G p.G981= | Silent (SNP) | VAF 57/407 reads (14%) | called by muse, mutect2, varscan2
- COL6A5 | c.945G>T p.G315= | Silent (SNP) | VAF 82/398 reads (21%) | called by muse, mutect2, varscan2
- CPLANE2 | c.85C>T p.L29= | Silent (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- CSPG4 | c.2427C>T p.A809= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- CYP27C1 | c.462A>G p.G154= | Silent (SNP) | VAF 52/303 reads (17%) | called by muse, mutect2, varscan2
- DIDO1 | c.5805A>G p.E1935= | Silent (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- EPHA10 | c.1173G>C p.P391= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- ESYT3 | c.897G>A p.L299= | Silent (SNP) | VAF 42/364 reads (12%) | catalogued as rs1171487569; called by muse, mutect2, varscan2
- GLYATL2 | c.375A>G p.V125= | Silent (SNP) | VAF 45/286 reads (16%) | called by muse, mutect2, varscan2
- HSF4 | c.324C>T p.R108= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs1161530054; called by muse, mutect2
- IGSF9B | c.1056A>G p.P352= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- INTS6 | c.777G>A p.Q259= | Silent (SNP) | VAF 105/261 reads (40%) | catalogued as rs753334868; called by muse, mutect2, varscan2
- IPO4 | c.447G>T p.R149= | Silent (SNP) | VAF 54/224 reads (24%) | called by muse, mutect2, varscan2
- KANSL3 | c.1203C>A p.L401= | Silent (SNP) | VAF 98/291 reads (34%) | called by muse, mutect2, varscan2
- KCNT1 | c.657C>A p.V219= (on ENST00000488444; = p.V238= on NM_020822.3) | Silent (SNP) | VAF 114/353 reads (32%) | called by muse, mutect2, varscan2
- LEPR | c.939G>T p.L313= | Silent (SNP) | VAF 67/459 reads (15%) | called by muse, mutect2, varscan2
- LRRC37A | c.3816G>A p.S1272= | Silent (SNP) | VAF 309/663 reads (47%) | called by muse, mutect2, varscan2
- LRRC66 | c.1233C>T p.S411= | Silent (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- MAGEC3 | c.342G>T p.L114= | Silent (SNP) | VAF 70/113 reads (62%) | catalogued as COSV71610277; called by muse, mutect2, varscan2
- MCRS1 | c.37C>T p.L13= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs940755078; called by muse, mutect2, varscan2
- MPL | c.297G>A p.E99= | Silent (SNP) | VAF 56/333 reads (17%) | catalogued as COSV65244861; called by muse, mutect2, varscan2
- MRC2 | c.4074C>A p.G1358= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- NOC4L | c.636G>T p.T212= | Silent (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- OR4N2 | c.120T>A p.P40= | Silent (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- OR51M1 | c.558C>A p.L186= | Silent (SNP) | VAF 68/377 reads (18%) | called by muse, mutect2, varscan2
- OTOS | c.150T>C p.Y50= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs761756958; called by muse, mutect2, varscan2
- PCBP1 | c.513C>T p.S171= | Silent (SNP) | VAF 80/246 reads (33%) | called by muse, mutect2, varscan2
- PCDHA4 | c.390G>A p.P130= | Silent (SNP) | VAF 56/292 reads (19%) | catalogued as rs550530931; called by muse, mutect2, varscan2
- PIK3AP1 | c.1545G>C p.T515= | Silent (SNP) | VAF 45/324 reads (14%) | called by muse, mutect2, varscan2
- PKHD1 | c.9600T>C p.L3200= | Silent (SNP) | VAF 404/1042 reads (39%) | called by muse, mutect2, varscan2
- PKN3 | c.2610C>A p.A870= | Silent (SNP) | VAF 129/299 reads (43%) | called by muse, mutect2, varscan2
- PP2D1 | c.1776C>T p.G592= | Silent (SNP) | VAF 178/520 reads (34%) | catalogued as rs939132953; called by muse, mutect2, varscan2
- RPAP1 | c.2766G>T p.P922= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100427130; called by muse, mutect2, varscan2
- RTL8C | c.229C>T p.L77= | Silent (SNP) | VAF 34/49 reads (69%) | called by muse, mutect2, varscan2
- SERPING1 | c.654C>T p.V218= | Silent (SNP) | VAF 83/289 reads (29%) | called by muse, mutect2, varscan2
- SHROOM4 | c.1284C>T p.T428= | Silent (SNP) | VAF 106/248 reads (43%) | called by muse, mutect2, varscan2
- SLC17A5 | c.171T>A p.R57= | Silent (SNP) | VAF 40/574 reads (7%) | called by muse, mutect2
- SLC38A8 | c.1203A>G p.G401= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- SLC5A8 | c.1401T>A p.P467= | Silent (SNP) | VAF 52/399 reads (13%) | called by muse, mutect2, varscan2
- SLC6A19 | c.879C>T p.N293= | Silent (SNP) | VAF 93/302 reads (31%) | catalogued as rs372112141; called by muse, mutect2, varscan2
- SORCS1 | c.603C>T p.S201= | Silent (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- SRCIN1 | c.96G>T p.G32= | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- SYNE1 | c.16005G>C p.V5335= (on ENST00000367255 / NM_182961.4; = p.V5264= on NM_033071.3) | Silent (SNP) | VAF 23/628 reads (4%) | called by muse, mutect2
- TEX15 | c.3102A>G p.A1034= (on ENST00000256246; = p.A1417= on NM_001350162.2) | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs773008300; called by muse, mutect2, varscan2
- TMEM132C | c.2706C>A p.P902= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.87A>G p.P29= | Silent (SNP) | VAF 56/150 reads (37%) | called by muse, mutect2
- TRIM50 | c.201C>T p.P67= | Silent (SNP) | VAF 64/224 reads (29%) | called by muse, mutect2, varscan2
- TRMT1L | c.1449A>G p.Q483= | Silent (SNP) | VAF 44/394 reads (11%) | catalogued as rs768938479, COSV62272676; called by muse, mutect2, varscan2
- TSHZ1 | c.1437G>T p.P479= (on ENST00000580243 / NM_001308210.2; = p.P434= on NM_005786.6) | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV59005514; called by muse, mutect2, varscan2
- VWA7 | c.2025G>A p.V675= | Silent (SNP) | VAF 91/165 reads (55%) | called by muse, mutect2, varscan2
- WDR81 | c.5613C>T p.P1871= (on ENST00000409644 / NM_001163809.2; = p.P820= on NM_152348.4) | Silent (SNP) | VAF 87/213 reads (41%) | called by muse, mutect2, varscan2
- ZNF585A | c.936A>G p.Q312= (on ENST00000292841 / NM_001288800.2; = p.Q257= on NM_152655.3) | Silent (SNP) | VAF 189/454 reads (42%) | catalogued as rs780703670; called by muse, mutect2, varscan2
- ZNF831 | c.3528A>T p.S1176= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ZSCAN4 | c.795T>A p.G265= | Silent (SNP) | VAF 127/359 reads (35%) | called by muse, mutect2, varscan2
- AC073621.1 | n.385A>G | RNA (SNP) | VAF 135/343 reads (39%) | catalogued as rs1049715734; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9382T>C | Intron (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- ASTN1 | c.1120+250A>C | Intron (SNP) | VAF 64/560 reads (11%) | called by muse, mutect2, varscan2
- BCAP29 | chr7:107621750 A>G | 3'Flank (SNP) | VAF 86/298 reads (29%) | called by muse, mutect2, varscan2
- C6orf118 | c.-19A>G | 5'UTR (SNP) | VAF 48/119 reads (40%) | catalogued as COSV100024650; called by muse, mutect2, varscan2
- COL6A4P1 | n.830A>T | RNA (SNP) | VAF 93/276 reads (34%) | called by muse, mutect2, varscan2
- CXCL12 | c.*390C>T | 3'UTR (SNP) | VAF 28/204 reads (14%) | called by muse, mutect2, varscan2
- DCAF17 | c.*3161C>G | 3'UTR (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- DNAJC19 | chr3:180989760 C>A | 5'Flank (SNP) | VAF 59/234 reads (25%) | called by muse, mutect2, varscan2
- DOCK4 | c.5014-715G>T | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- DPH2 | c.260+47A>G | Intron (SNP) | VAF 31/178 reads (17%) | catalogued as rs763357329; called by muse, mutect2, varscan2
- DYNLRB1 | c.-5C>A | 5'UTR (SNP) | VAF 8/47 reads (17%) | catalogued as COSV55963647; called by muse, mutect2
- DYNLRB1 | c.-3G>A | 5'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs777637709; called by muse, mutect2
- GIPR | c.855-49G>C | Intron (SNP) | VAF 12/251 reads (5%) | catalogued as rs1160540677; called by muse, mutect2
- GOLGA8R | c.348+67C>G | Intron (SNP) | VAF 43/304 reads (14%) | called by mutect2, varscan2
- KCNB1 | c.-121G>T | 5'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- LRRC37BP1 | n.1273A>G | RNA (SNP) | VAF 26/60 reads (43%) | catalogued as rs1019903672; called by mutect2, varscan2
- LSM4 | c.4-18G>A | Intron (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1336-1627C>T | Intron (SNP) | VAF 45/521 reads (9%) | called by muse, mutect2
- PRR12 | chr19:49594813 C>T | 5'Flank (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- RAD54B | c.1518+30A>G | Intron (SNP) | VAF 38/131 reads (29%) | called by muse, mutect2, varscan2
- RNF2 | c.*1G>A | 3'UTR (SNP) | VAF 23/175 reads (13%) | catalogued as rs1029715259; called by muse, mutect2, varscan2
- RPAP1 | c.3795+131_3795+139del | Intron (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- SLCO4A1 | chr20:62642193 G>A | 5'Flank (SNP) | VAF 13/75 reads (17%) | catalogued as rs1252470448; called by muse, mutect2, varscan2
- SNORD116-27 | n.19A>T | RNA (SNP) | VAF 57/338 reads (17%) | called by muse, mutect2, varscan2
- SORBS2 | c.-46+874T>A | Intron (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- SPATA8 | n.784G>A | RNA (SNP) | VAF 21/155 reads (14%) | catalogued as rs1439925658; called by muse, mutect2, varscan2
- ST3GAL4 | c.16+40G>T | Intron (SNP) | VAF 25/140 reads (18%) | called by muse, mutect2, varscan2
- TGM7 | c.10+30G>A | Intron (SNP) | VAF 59/245 reads (24%) | catalogued as rs770281566; called by muse, mutect2, varscan2
- TMEM236 | c.*2062G>T | 3'UTR (SNP) | VAF 61/359 reads (17%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-130G>A | Intron (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10360+4364A>G | Intron (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- UMPS | c.*517G>T | 3'UTR (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- UMPS | c.*3844C>T | 3'UTR (SNP) | VAF 55/264 reads (21%) | called by muse, mutect2, varscan2
- ZNF207 | chr17:32373451 G>T | 3'Flank (SNP) | VAF 54/125 reads (43%) | called by muse, mutect2, varscan2
- ZNF90 | chr19:20121292 C>A | 3'Flank (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
